Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A2CO, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A2CO-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Consultation Report

Patient

Name:

MRN:

DOB:

Gender: F

HCN:

Ordering

MD:

Copy To:

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Specimen(s) Received

1. Thyroid: Right Upper parathyroid
2. Thyroid: right upper thyroid stitch marks upper pole

Diagnosis

1. No pathological diagnosis: Parathyroid (right upper) biopsy.
2. Papillary carcinoma, 2.9 cm, oncocytic variant, and follicular nodular disease: Thyroid (right) lobectomy specimen.

Synoptic Data

Procedure: Right thyroid lobectomy
Received: Fresh
Specimen Integrity: Intact
Specimen Size: Right lobe:

4.3 cm

3.0 cm

1.5 cm

Specimen Weight:

11.58 g

Tumor Focality:

Unifocal

----- DOMINANT TUMOR -----

Tumor Laterality:

Tumor Size:

Greatest dimension: 2.9cm

Additional dimension: 2.1 cm

Additional dimension: 1.4 cm

Histologic Type:

Papillary carcinoma, oncocytic or oxyphilic variant

Follicular architecture

Oncocytic or oxyphilic cytomorphology

Histologic Grade:

Not applicable

Margins:

Margins uninvolved by carcinoma

Tumor Capsule:

Totally encapsulated

ICD-0-3
carcinoma, papillary, follicular
variant 8340/3
Site: thyroid, nos 873.9 lw 6/18/11

per TSS, follicular variant = 100%

[page 2 of 2]
Tumor Capsular Invasion:	Present, extent minimal
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT2: Tumor more than 2 cm, but not more than 4 cm, limited to thyroid
Regional Lymph Nodes (pN):	pNX: Regional lymph nodes cannot be assigned Number of regional lymph nodes examined: 0 Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Adenomatoid nodule(s) or Nodular follicular disease Thyroiditis, focal (nonspecific)

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically

verified by:

Gross Description

1. The specimen labelled with the patient's name and as "Thyroid: Right upper parathyroid" consists of a tiny fragment of tissue that weighs 0.004 g and measures 0.1 x 0.1 x 0.1 cm. It is frozen for intraoperative consultation.

1A frozen section block resubmitted

2. The specimen labeled with the patient's name and as "Thyroid: Right upper thyroid stitch marks upper pole", consists of a lobe of thyroid that is oriented with a suture. It measures 4.3 cm SI x 3.0 cm ML x 1.5 cm AP and weighs 11.58 g. The external surfaces have fibrous adhesions. No parathyroid glands or lymph nodes are identified grossly. The external surface is painted with Silver nitrate. The upper lobe contains two well delineated nodules that measure 2.1 cm SI x 2.9 cm ML x 1.4 cm AP and 0.6 cm SI x 0.7 cm ML x 0.6 cm AP. The remainder of the thyroid tissue is unremarkable. Sections of nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

2A-J lobe, superior to inferior

Quick Section Diagnosis

1. Right Upper parathyroid - 1A Parathyroid tissue present (deeper section obtained)

Slide received at

Reported to

MD

Source: NCI Genomic Data Commons file d33fbc96-8556-47be-a64a-ee4ba6a73b73 (TCGA-EM-A2CO.AAD6A295-FE0C-46FF-A9C2-D2A75EE02AFA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).